Somatic mutation profile of tumor specimen TCGA-EB-A6L9-06A (aliquot TCGA-EB-A6L9-06A-11D-A32N-08) from TCGA case TCGA-EB-A6L9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.2 years (20,537 days).
Specimen TCGA-EB-A6L9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6f4d6ca-1588-4416-8c8c-094d5d90ca79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A6L9-10A (Blood Derived Normal), aliquot TCGA-EB-A6L9-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f615883f-9176-4b4f-8e81-c239e5b4aae9

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7, Splice Site 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.1407-2A>G p.X469_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV63979292; called by muse, mutect2
- CCDC87 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100040093; called by muse, mutect2, varscan2
- CDH10 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52573130, COSV52579326; called by muse, mutect2
- CYP2A13 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1568368380, COSV100386926; called by muse, mutect2, varscan2
- CYTH2 | c.434+1G>A p.X145_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100287281; called by muse, mutect2, varscan2
- DUS3L | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV100288370; called by muse, mutect2, varscan2
- FCRL1 | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1484879134; called by muse, mutect2
- IGHA1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs746848629; called by muse, mutect2, varscan2
- MGAM | c.4062C>G p.V1354= | Splice Region (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101527606; called by muse, mutect2, varscan2
- OR5M10 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV101595912; called by muse, mutect2, varscan2
- PARP10 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.293); catalogued as rs1332622262, COSV100478170; called by muse, mutect2, varscan2
- SFXN1 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100369388; called by muse, mutect2
- XPO4 | c.3412G>C p.E1138Q | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV55012025; called by muse, mutect2
- ZNF14 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100694102; called by muse, mutect2
- AGAP1 | c.954C>T p.F318= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100366270; called by muse, mutect2, varscan2
- ATP1A2 | c.1902T>C p.G634= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV100768013; called by muse, mutect2
- CHGB | c.201C>T p.D67= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs369408703; called by muse, mutect2
- FUT8 | c.633G>A p.V211= (on ENST00000360689 / NM_001371534.1; = p.V48= on NM_004480.4) | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs776199529, COSV100651556; called by muse, mutect2, varscan2
- PSD4 | c.2397C>T p.G799= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99830737, COSV99831305; called by muse, mutect2, varscan2
- ZFYVE1 | c.708G>A p.T236= | Silent (SNP) | VAF 4/81 reads (5%) | catalogued as rs1466943158, COSV59613950; called by muse, mutect2
- ZNF681 | c.1401A>G p.T467= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV101267527; called by muse, mutect2, varscan2
